Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A4UL, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A4UL-01A (Primary Tumor).

[page 1 of 4]
Additional Copy to:

Clinical Diagnosis & History:

Patient with bilateral small thyroid nodules, FNA of right sided nodule shows PTC.

Specimens Submitted:

- 1: Tissue of cricoid cartilage (fs)
- 2: Pretracheal lymph node
- 3: Delphian lymph node
- 4: Pyramidal lobe
- 5: Total thyroidectomy

DIAGNOSIS:

1. Tissue of cricoid cartilage; excision (fs):
- Benign thyroid tissue.
2. Pretracheal lymph node; excision:
- One benign lymph node (0/1).
3. Delphian lymph node; excision:
- One benign lymph node (0/1).
4. Pyramidal lobe; excision:
- Benign thyroid tissue with cautery artifact.
- One benign lymph node (0/1).

5. Total thyroidectomy:

Part # 5

Tumor Type:

Papillary carcinoma, classical type

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Tumor Location:

Left lobe

Tumor Size:

Greatest diameter is 1.1 cm.

Tumor Encapsulation:

None identified

1CD-0-3

Carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS 673.9

hw
10/27/12

[page 2 of 4]
Blood vessel invasion:
Not identified

Extrathyroid Extension:
Not identified

Surgical Margins:
Tumor is present at the inked and cauterized margin.

Tumor Multicentricity:
Multiple foci of papillary microcarcinoma (9 foci) are present in both lobes ranging from 0.15 to 0.8 cm in greatest dimension

Adenoma(s) (away from the carcinoma):
Not identified

Non-Neoplastic Thyroid:
Exhibits nodular hyperplasia

Parathyroid Glands:
One unremarkable parathyroid gland is identified on the right side

Note:

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result

Special Stain
RECUT

Comment

Gross Description:

1. The specimen is received fresh for frozen section consultation, labeled "tissue of cricoid cartilage", and consists of a fragment of tan-pink soft tissue measuring 0.4 x 0.3 x 0.1 cm. The specimen is entirely submitted for frozen section.

Summary of sections:
FSC - frozen section control

2. The specimen is received fresh, labeled "Pre-tracheal lymph node" and consists of a firm tan lymph node measuring 0.3 x 0.2 x 0.1 cm. The lymph node is entirely submitted.

Summary of sections:
LN - lymph node

3. The specimen is received fresh, labeled "Delphian lymph node" and consists of a possible lymph node measuring 1.5 x 1.0 x 0.2 cm. The specimen is entirely submitted.

Summary of sections:
PLN - possible lymph node

[page 3 of 4]
4. The specimen is received fresh, labeled "Pyramidal lobe" and consists of an irregular fragment of soft tissue measuring 1.3 x 0.5 x 0.4 cm. The specimen is bisected and entirely submitted.

Summary of sections:
U - undesignated

5. The specimen is received fresh, labeled "total thyroidectomy stitch marks left lobe of thyroid", and consists of a thyroid weighing 16.4 g. The right lobe measures 4.2 x 3.2 x 1.1 cm, the left lobe measures 4.1 x 3.3 x 1.1 cm and the isthmus measures 1.4 x 0.5 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a 1.1 x 0.7 x 0.6 cm nodule that is tan white and well-circumscribed. The nodule is located in the left inferior lobe. Sections through the remaining tissue reveals an additional tan white well circumscribed nodule that is located in the right upper pole and measures 0.7 x 0.5 x 0.4 cm. The remaining thyroid parenchyma is red brown and beefy. Representative sections of the specimen are submitted for TPS. The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:
NL - nodule left, entirely submitted
NR - nodule right, entirely submitted
RL - right lobe
LL - left lobe
IS - isthmus

Summary of Sections:

Part 1: Tissue of cricoid cartilage (fs)

Block	Sect. Site	PCs
1	fsc	1

Part 2: Pretracheal lymph node

Block	Sect. Site	PCs
1	LN	1

Part 3: Delphian lymph node

Block	Sect. Site	PCs
1	PLN	1

Part 4: Pyramidal lobe

Block	Sect. Site	PCs
1	U	2

Part 5: Total thyroidectomy

Block	Sect. Site	PCs
1	IS	1
6	LL	6
1	NL	1
1	NR	1
7	RL	7

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: Benign thyroid tissue

[page 4 of 4]
PERMANENT DIAGNOSIS: Same

Prior Malignancy/History		✓

10/27/12

Source: NCI Genomic Data Commons file 550965d0-351a-49b4-8040-41f67e3664b9 (TCGA-DJ-A4UL.335DABDB-7CD0-4035-A46E-505EB4BF0359.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).